Somatic mutation profile of tumor specimen 0E1205 from CCDI case PBCVWU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1205: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3166f54-1836-4809-839f-4316f23f260e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E11ZJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e68263a-6459-4b79-8a99-1690a5e020ac

The open-access MAF lists 62 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 16, Intron 7, 3'UTR 4, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 122/634 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACRBP | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 116/571 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs577478690, COSV57524289; called by muse, mutect2, varscan2
- ADARB2 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 169/374 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760242914, COSV67227711; called by muse, mutect2, varscan2
- ARL6 | c.525C>G p.D175E | Missense Mutation (SNP) | VAF 54/667 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.012); catalogued as COSV60117141; called by muse, mutect2
- CCDC168 | c.8215G>T p.E2739* | Nonsense Mutation (SNP) | VAF 28/550 reads (5%) | catalogued as rs1165338114; called by muse, mutect2
- DNAH11 | c.13184G>A p.R4395Q | Missense Mutation (SNP) | VAF 39/660 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs368249392, COSV60954764; called by muse, mutect2
- DNAJC16 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 586/1002 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs367639467; called by muse, mutect2, varscan2
- KLK12 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 78/424 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99142090; called by muse, mutect2
- MECOM | c.1499C>A p.A500D (on ENST00000468789 / NM_001105078.4; = p.A688D on NM_004991.4) | Missense Mutation (SNP) | VAF 238/517 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs762099223, COSV52963199; called by mutect2, varscan2
- MYO1G | c.2050G>A p.V684M | Missense Mutation (SNP) | VAF 221/456 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867414113; called by muse, mutect2, varscan2
- PPP1R32 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 107/409 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1401018122; called by muse, mutect2, varscan2
- PRDM15 | c.1565-2A>G p.X522_splice | Splice Site (SNP) | VAF 135/602 reads (22%) | catalogued as rs1158782438; called by muse, mutect2, varscan2
- TBL3 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 88/406 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs145453264; called by muse, mutect2, varscan2
- TNRC6A | c.3667C>G p.Q1223E | Missense Mutation (SNP) | VAF 31/768 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV59365125; called by muse, mutect2
- ZNF347 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61971387; called by muse, mutect2
- ARHGEF5 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 106/1322 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); called by muse, mutect2
- C4BPA | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 27/706 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0.01); called by muse, mutect2
- CARS2 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 30/584 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2
- CCDC192 | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 17/489 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- CCL3 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 280/669 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CPD | c.3433G>C p.D1145H | Missense Mutation (SNP) | VAF 30/694 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- EYA1 | c.1048A>T p.R350W | Missense Mutation (SNP) | VAF 24/613 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KNTC1 | c.6252C>G p.H2084Q | Missense Mutation (SNP) | VAF 80/838 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.084); called by muse, mutect2
- L3MBTL2 | c.1174+1G>C p.X392_splice | Splice Site (SNP) | VAF 25/522 reads (5%) | called by muse, mutect2
- MORC1 | c.2256A>T p.Q752H | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- MSC | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- MYH6 | c.2725C>G p.Q909E | Missense Mutation (SNP) | VAF 302/733 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- OR2A12 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 167/695 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- PLCH1 | c.4454A>T p.K1485I (on ENST00000340059 / NM_001130960.2; = p.K1477I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/567 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PRAMEF18 | c.1406A>G p.E469G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- TIPARP | c.1860C>A p.D620E | Missense Mutation (SNP) | VAF 125/501 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBE3C | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 128/694 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- WDR87 | c.2898G>C p.K966N | Missense Mutation (SNP) | VAF 109/581 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLDND1 | c.477T>G p.L159= | Silent (SNP) | VAF 28/682 reads (4%) | called by muse, mutect2
- GALNT17 | c.300G>A p.P100= | Silent (SNP) | VAF 99/499 reads (20%) | catalogued as rs770531592, COSV61167193; called by muse, mutect2, varscan2
- H2AC14 | c.381T>G p.T127= | Silent (SNP) | VAF 157/383 reads (41%) | called by muse, mutect2, varscan2
- IL5RA | c.465C>T p.C155= | Silent (SNP) | VAF 360/746 reads (48%) | called by muse, mutect2, varscan2
- NKD2 | c.930G>A p.S310= | Silent (SNP) | VAF 61/240 reads (25%) | catalogued as rs147626744; called by muse, mutect2, varscan2
- OR51E1 | c.285C>A p.I95= | Silent (SNP) | VAF 239/498 reads (48%) | catalogued as COSV67810346; called by muse, mutect2, varscan2
- PCDH9 | c.2031T>C p.S677= | Silent (SNP) | VAF 232/531 reads (44%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.81C>T p.R27= | Silent (SNP) | VAF 117/557 reads (21%) | catalogued as rs779562339, COSV53899615; called by muse, varscan2
- PLEKHA1 | c.939C>T p.F313= | Silent (SNP) | VAF 46/1000 reads (5%) | called by muse, mutect2
- RSPRY1 | c.615C>G p.V205= | Silent (SNP) | VAF 40/812 reads (5%) | called by muse, mutect2
- SHB | c.1362T>C p.F454= | Silent (SNP) | VAF 52/425 reads (12%) | called by muse, mutect2, varscan2
- SMYD1 | c.1137C>T p.D379= | Silent (SNP) | VAF 85/496 reads (17%) | catalogued as rs1042842559, COSV70225437, COSV70225900; called by muse, mutect2, varscan2
- SPATA31A6 | c.876C>G p.A292= | Silent (SNP) | VAF 68/952 reads (7%) | called by muse, mutect2
- SPATA7 | c.1797T>G p.V599= | Silent (SNP) | VAF 52/267 reads (19%) | called by muse, mutect2, varscan2
- TRMT10A | c.417G>A p.V139= | Silent (SNP) | VAF 25/636 reads (4%) | catalogued as COSV56746183; called by muse, mutect2
- URI1 | c.613C>T p.L205= | Silent (SNP) | VAF 107/693 reads (15%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 24/666 reads (4%) | called by muse, mutect2
- BRD7 | c.-28G>T | 5'UTR (SNP) | VAF 52/109 reads (48%) | called by muse, mutect2, varscan2
- ELAVL4 | chr1:50103958 C>G | 5'Flank (SNP) | VAF 63/445 reads (14%) | called by muse, mutect2, varscan2
- KCNQ1 | c.386+16182C>A | Intron (SNP) | VAF 59/457 reads (13%) | called by muse, mutect2, varscan2
- LIN9 | c.244+513C>T | Intron (SNP) | VAF 40/288 reads (14%) | catalogued as rs376356846; called by muse, mutect2, varscan2
- MARVELD2 | c.*28T>C | 3'UTR (SNP) | VAF 64/247 reads (26%) | called by muse, mutect2, varscan2
- MYCN | c.*58A>G | 3'UTR (SNP) | VAF 397/906 reads (44%) | called by muse, mutect2, varscan2
- NSD3 | c.2612-45G>A | Intron (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- SORBS2 | c.3085-57A>G | Intron (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- TGFB3 | c.516+63G>T | Intron (SNP) | VAF 104/225 reads (46%) | called by muse, mutect2, varscan2
- TNNT3 | c.715-737C>T | Intron (SNP) | VAF 211/472 reads (45%) | catalogued as rs745840491, COSV99547993, COSV99548354; called by muse, mutect2, varscan2
- UTY | c.1186-560A>T | Intron (SNP) | VAF 12/356 reads (3%) | called by muse, mutect2
- WIPI2 | c.*10G>C | 3'UTR (SNP) | VAF 83/315 reads (26%) | called by muse, mutect2, varscan2
